Somatic mutation profile of tumor specimen TCGA-GF-A6C9-06A (aliquot TCGA-GF-A6C9-06A-11D-A30X-08) from TCGA case TCGA-GF-A6C9, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 78.8 years (28,778 days).
Specimen TCGA-GF-A6C9-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a3681c2-09b4-47b9-8697-001dfbcc4cb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GF-A6C9-10A (Blood Derived Normal), aliquot TCGA-GF-A6C9-10A-01D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/296a905f-e5e8-463e-a64d-b9dee11571e9

The open-access MAF lists 3,255 somatic variants for this specimen: 2,052 protein-altering or splice-affecting, 1,121 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,865, Silent 1,121, Nonsense Mutation 115, Intron 35, Splice Region 31, RNA 29, Splice Site 25, Frame Shift Del 9, 3'Flank 7, 5'UTR 5, 3'UTR 5, Translation Start Site 4.

Variants (750 of 3,255; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.394); catalogued as rs138157885, CM074663; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARID1B | c.3496C>T p.Q1166* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as rs1554231904, COSV51666413; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP1A3 | c.2482G>A p.E828K (on ENST00000545399 / NM_001256214.2; = p.E815K on NM_152296.5) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs387907281, CM127592, COSV57486474; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.4072C>T p.R1358* | Nonsense Mutation (SNP) | VAF 7/108 reads (6%) | catalogued as rs794728057, COSV58588536; ClinVar: pathogenic; called by muse, mutect2
- DMD | c.4375C>T p.R1459* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as rs398123953, CM950342, COSV63738314; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EBF2 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 16/109 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV68776268, COSV68778111; called by muse, varscan2
- EGFR | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs121913231, COSV51778029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as rs763413735, COSV59534728; called by mutect2, varscan2
- GABRA1 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795283, COSV50115193; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNJ8 | c.1250G>A p.G417E | Missense Mutation (SNP) | VAF 16/95 reads (17%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.131); catalogued as COSV53715303; called by muse, mutect2, varscan2
- KNSTRN | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 11/73 reads (15%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as rs868438023, COSV51103508; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RIPPLY2 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100859440, COSV63746041; called by muse, mutect2, varscan2
- RORC | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774357869, CM158000, COSV100562072, COSV59094013; ClinVar: pathogenic; called by mutect2, varscan2
- SULT2B1 | c.232G>A p.E78K (on ENST00000201586 / NM_177973.2; = p.E63K on NM_004605.2) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs140526640; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 12/96 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.205); catalogued as rs142762485, COSV53196450; called by muse, mutect2, varscan2
- ABCA1 | c.3551C>T p.S1184F | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.042); catalogued as COSV66069581; called by muse, mutect2, varscan2
- ABCA13 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as rs572340175, COSV70025642; called by muse, mutect2, varscan2
- ABCA13 | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV70041356; called by muse, mutect2, varscan2
- ABCA13 | c.9311C>T p.S3104F | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71283997; called by muse, mutect2, varscan2
- ABCA2 | c.2246C>T p.S749F (on ENST00000614293; = p.S719F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV55797505; called by muse, mutect2, varscan2
- ABCA4 | c.3835G>A p.D1279N | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV64672633, COSV64676748; called by muse, mutect2, varscan2
- ABCA4 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as rs867875828, CM149724, COSV100933159, COSV64674648; ClinVar: uncertain significance; called by mutect2, varscan2
- ABCA6 | c.836C>T p.S279F | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52643644; called by muse, mutect2
- ABCA7 | c.2453G>A p.G818E | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.168); catalogued as COSV54035727; called by muse, mutect2, varscan2
- ABCB1 | c.2087C>T p.S696F | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55947943; called by muse, mutect2, varscan2
- ABCB4 | c.2140G>A p.G714R | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55937811; called by muse, mutect2, varscan2
- ABCB4 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as rs370195624, CM159632; called by muse, mutect2, varscan2
- ABCC2 | c.2348T>A p.L783H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64988137; called by muse, mutect2, varscan2
- ABCC3 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53327428; called by mutect2, varscan2
- ABCD2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1362852198, COSV58054378; called by muse, mutect2
- ABLIM1 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV53313834; called by muse, mutect2, varscan2
- AC100868.1 | c.1709G>A p.R570K | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0.219); catalogued as COSV51848629; called by mutect2, varscan2
- ACAP1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.326); catalogued as COSV50138864; called by muse, mutect2, varscan2
- ACOT12 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as COSV100296598, COSV56897382; called by muse, mutect2
- ACP3 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as rs149109145; called by muse, mutect2
- ACP6 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65077577, COSV65077742; called by muse, mutect2, varscan2
- ACSBG2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV53123187; called by muse, mutect2, varscan2
- ACSL4 | c.1960C>T p.R654* (on ENST00000340800 / NM_022977.2; = p.R613* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/81 reads (17%) | catalogued as CM151038, COSV100538347, COSV61614626; called by muse, mutect2, varscan2
- ACTL8 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV64862483; called by muse, mutect2, varscan2
- ACTRT1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.058); catalogued as COSV64419395; called by muse, mutect2, varscan2
- ADAM15 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs758022424, COSV55058819; called by muse, mutect2, varscan2
- ADAM18 | c.1247A>T p.K416M | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs1278449768, COSV55853223; called by muse, mutect2, varscan2
- ADAM19 | c.1503G>A p.M501I | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV57437319; called by muse, mutect2, varscan2
- ADAM23 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as COSV52226611; called by muse, mutect2, varscan2
- ADAM28 | c.2206G>A p.D736N | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as COSV56098447, COSV56099005; called by muse, mutect2, varscan2
- ADAM30 | c.1815G>A p.M605I | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV65561877; called by muse, mutect2
- ADAM7 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61757471, COSV51536147; called by muse, mutect2, varscan2
- ADAMTS12 | c.3089G>A p.R1030K | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61274894; called by muse, mutect2
- ADAMTS16 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.809); catalogued as COSV56999397, COSV99941133; called by muse, mutect2, varscan2
- ADAMTS16 | c.2410G>A p.D804N | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57003456, COSV57011657; called by muse, mutect2
- ADAMTS18 | c.2179C>T p.H727Y | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV51399503; called by muse, mutect2
- ADAMTS18 | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV51414758, COSV51419511; called by muse, mutect2, varscan2
- ADAMTS19 | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.278); catalogued as COSV50785156; called by muse, mutect2
- ADAMTS20 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.841); catalogued as COSV67128809, COSV67131706; called by muse, varscan2
- ADAMTS4 | c.2264G>A p.G755E | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV63489255, COSV63490967; called by muse, mutect2
- ADAMTS5 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV53183872; called by muse, mutect2, varscan2
- ADAMTS7 | c.3926C>T p.S1309F | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV101183151; called by muse, varscan2
- ADAMTS8 | c.2632G>A p.D878N | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1295404889, COSV57296393; called by muse, mutect2, varscan2
- ADAMTS8 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV57296410; called by muse, mutect2, varscan2
- ADAMTS9 | c.5431G>A p.D1811N | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.595); catalogued as rs770275540, COSV55788486; called by mutect2, varscan2
- ADAMTSL3 | c.2518C>T p.Q840* | Nonsense Mutation (SNP) | VAF 12/120 reads (10%) | catalogued as rs1447616197, COSV54464152; called by muse, mutect2
- ADAMTSL3 | c.2881A>C p.I961L | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV54464167; called by muse, mutect2
- ADCY4 | c.1585G>A p.G529R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.036); catalogued as COSV60256774; called by muse, mutect2, varscan2
- ADCY7 | c.1871C>T p.S624F | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV54269941; called by muse, mutect2, varscan2
- ADGRA2 | c.1205G>A p.R402Q | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.089); catalogued as rs757509633, COSV59442329; called by muse, mutect2
- ADGRB3 | c.2354C>T p.S785F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65414642; called by muse, mutect2
- ADGRB3 | c.3410C>T p.S1137L | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV53245614; called by muse, varscan2
- ADGRB3 | c.3984G>A p.M1328I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53256988; called by muse, mutect2, varscan2
- ADGRB3 | c.4555C>T p.Q1519* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as rs1322137537, COSV53257003; called by muse, varscan2
- ADGRE1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs376031317, COSV51672479; called by mutect2, varscan2
- ADGRF5 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as rs370529218; called by muse, varscan2
- ADGRG3 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as COSV59652240; called by muse, mutect2, varscan2
- ADGRG4 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.46); catalogued as COSV54952783; called by muse, mutect2, varscan2
- ADGRG4 | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs866052593, COSV54949311; called by muse, mutect2, varscan2
- ADGRG4 | c.5399C>T p.S1800F | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs1482804899, COSV54964369; called by muse, mutect2, varscan2
- ADGRG4 | c.8264C>T p.S2755F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1209587233, COSV54964383; called by muse, mutect2, varscan2
- ADGRG4 | c.9082G>A p.G3028R | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99795929; called by muse, mutect2, varscan2
- ADGRG4 | c.9083G>A p.G3028E | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs371979123, COSV54950602; called by muse, mutect2, varscan2
- ADGRG7 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56297973, COSV56300220; called by muse, mutect2, varscan2
- ADGRL2 | c.2636G>A p.R879Q (on ENST00000370717 / NM_001366005.1; = p.R866Q on NM_012302.4) | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373312947; called by muse, mutect2, varscan2
- ADGRL2 | c.2846G>A p.R949K (on ENST00000370717 / NM_001366005.1; = p.R936K on NM_012302.4) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs1446392973, COSV54683299; called by muse, mutect2, varscan2
- ADGRV1 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67993212; called by muse, mutect2
- ADGRV1 | c.9439C>T p.R3147* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs769681955, COSV67985825; called by muse, mutect2, varscan2
- ADGRV1 | c.13373C>T p.T4458I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV67978874; called by muse, mutect2, varscan2
- ADH1A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1039874400, COSV52924296; called by muse, mutect2
- ADHFE1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52555998; called by muse, mutect2
- AFAP1L2 | c.2402G>A p.G801D (on ENST00000304129 / NM_001351075.1; = p.G797D on NM_032550.3 and 11 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV58417853; called by muse, mutect2, varscan2
- AFAP1L2 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV58417861; called by muse, mutect2, varscan2
- AFAP1L2 | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs780442826, COSV58417867; called by mutect2, varscan2
- AFF2 | c.3346G>A p.D1116N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.748); catalogued as rs782493302, COSV53976858, COSV54002946; called by muse, mutect2, varscan2
- AGAP1 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs977852432, COSV58336880; called by muse, mutect2, varscan2
- AGAP3 | c.698C>T p.T233I (on ENST00000622464; = p.T269I on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58996041; called by muse, mutect2
- AHNAK2 | c.7067C>T p.S2356F | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs1406759736, COSV100315231, COSV60926830; called by muse, mutect2, varscan2
- AHNAK2 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1336709319, COSV60926840; called by muse, mutect2, varscan2
- AJAP1 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV65453330; called by muse, mutect2, varscan2
- AK5 | c.101C>T p.P34L (on ENST00000354567 / NM_174858.3; = p.P8L on NM_012093.4) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV58356836; called by muse, mutect2, varscan2
- AKAP4 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62075317; called by muse, mutect2, varscan2
- AKR7A3 | c.794C>T p.S265L | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs954905577, COSV64389661; called by muse, mutect2, varscan2
- ALB | c.535C>T p.L179F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as COSV55738013; called by muse, mutect2, varscan2
- ALDH1A2 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51088733; called by muse, mutect2, varscan2
- ALG11 | c.1229C>T p.A410V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101584336; called by muse, mutect2, varscan2
- ALG13 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV52643806; called by muse, mutect2, varscan2
- ALG5 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV53506870; called by muse, mutect2, varscan2
- ALKBH3 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57024215; called by muse, mutect2, varscan2
- ALKBH8 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as COSV52837846; called by muse, mutect2
- ALOX15 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as rs745702295, COSV53400065; called by muse, mutect2, varscan2
- ALOX5 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs749902144, COSV65553942; called by muse, mutect2, varscan2
- ALPK2 | c.3876A>C p.E1292D | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV64496005; called by muse, mutect2, varscan2
- ALPK3 | c.3527G>A p.G1176E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV51938491; called by muse, mutect2, varscan2
- ALPK3 | c.4396G>A p.D1466N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs760060304, COSV51938505; called by muse, mutect2, varscan2
- AMER1 | c.1591C>T p.R531* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as CM117716, COSV57662882, COSV57669568; called by muse, mutect2, varscan2
- AMPD1 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62418197; called by muse, mutect2, varscan2
- AMPD1 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV62418211; called by muse, mutect2, varscan2
- AMPD2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV56649714; called by muse, mutect2, varscan2
- AMPD3 | c.877G>A p.E293K (on ENST00000396553 / NM_001025389.2; = p.E302K on NM_000480.3) | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs760590808, COSV67331501; called by muse, mutect2, varscan2
- AMY1C | c.879G>A p.K293= | Splice Region (SNP) | VAF 30/530 reads (6%) | catalogued as COSV64407220; called by muse, mutect2
- AMY2A | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 53/459 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs879420983, COSV70214849; called by muse, mutect2, varscan2
- AMY2B | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 100/795 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV63716708; called by muse, mutect2, varscan2
- AMY2B | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 48/494 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140826288; called by muse, mutect2, varscan2
- AMY2B | c.1040C>T p.P347L | Missense Mutation (SNP) | VAF 24/537 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100796301, COSV63716716, COSV63716753; called by muse, mutect2
- AMY2B | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV63716563; called by muse, mutect2
- ANG | c.370T>C p.F124L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.02); catalogued as CM1110463, COSV59012996; called by muse, mutect2, varscan2
- ANGPT4 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV67922534; called by muse, mutect2
- ANK2 | c.4021G>A p.E1341K | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52182329; called by muse, mutect2, varscan2
- ANK2 | c.7076C>T p.S2359L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV52154948; called by muse, mutect2, varscan2
- ANK3 | c.10141G>A p.E3381K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); catalogued as COSV55048770; called by muse, varscan2
- ANK3 | c.7003G>A p.E2335K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs769392075, COSV55047176; called by mutect2, varscan2
- ANK3 | c.6763C>T p.H2255Y | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.229); catalogued as rs370076474; called by muse, mutect2, varscan2
- ANK3 | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs867458540, COSV55076480; called by muse, varscan2
- ANKEF1 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1232813724, COSV65692304; called by muse, varscan2
- ANKRD11 | c.3104A>C p.K1035T | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV56369167; called by muse, mutect2, varscan2
- ANKS1A | c.2185G>A p.G729R | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100832127, COSV64463619; called by muse, mutect2, varscan2
- ANO3 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.846); catalogued as rs867157355, COSV56785901, COSV56812112; called by muse, mutect2, varscan2
- ANO3 | c.2003G>A p.G668E | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866202976, COSV56795878; called by muse, mutect2, varscan2
- ANO4 | c.1765G>A p.E589K (on ENST00000392977 / NM_001286615.2; = p.E554K on NM_178826.4) | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV54609063; called by muse, mutect2
- ANPEP | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV55593960; called by muse, mutect2
- ANXA1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.029); catalogued as rs868517148, COSV57412371; called by muse, mutect2, varscan2
- AOAH | c.1667G>A p.G556E | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV51748813; called by muse, mutect2, varscan2
- AOC1 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.485); catalogued as COSV62870380; called by muse, mutect2
- AOC3 | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as COSV53824546; called by muse, mutect2, varscan2
- APC | c.3079T>C p.Y1027H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs587781605, CD106432, COSV104379129, COSV57371689; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.12530G>A p.R4177Q | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1458728752, COSV51948378; called by muse, mutect2, varscan2
- APOB | c.7810C>T p.L2604F | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51948400; called by muse, mutect2, varscan2
- APOB | c.7562A>G p.D2521G | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51948410; called by muse, mutect2, varscan2
- APOB | c.6553A>C p.I2185L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.328); catalogued as COSV51948423; called by muse, mutect2
- APOB | c.1566G>A p.M522I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV51933081; called by muse, mutect2
- APOB | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51922910; called by muse, mutect2, varscan2
- APOH | c.63G>A p.R21= | Splice Region (SNP) | VAF 4/25 reads (16%) | catalogued as COSV52774580, COSV99235990; called by muse, mutect2, varscan2
- AQP9 | c.592C>T p.L198F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.098); catalogued as COSV54970272; called by muse, mutect2, varscan2
- AR | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM920997, CM973003, COSV65957192; called by muse, mutect2, varscan2
- ARAF | c.460T>C p.F154L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51694809; called by muse, mutect2, varscan2
- ARG1 | c.380C>A p.T127N | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV51581685; called by muse, mutect2, varscan2
- ARGFX | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1376020870, COSV57683473; called by muse, varscan2
- ARHGAP18 | c.1755T>G p.H585Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV63765777; called by muse, mutect2, varscan2
- ARHGAP22 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50970255; called by muse, mutect2, varscan2
- ARHGAP25 | c.1744G>A p.E582K (on ENST00000409202 / NM_001007231.3; = p.E574K on NM_014882.3) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.509); catalogued as COSV54906945; called by muse, mutect2, varscan2
- ARHGAP29 | c.2998G>A p.D1000N | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV53115625, COSV53116351; called by muse, mutect2, varscan2
- ARHGAP29 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs267598780, COSV53109793, COSV53115635; called by muse, mutect2, varscan2
- ARHGAP29 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV53115646; called by muse, mutect2, varscan2
- ARHGAP31 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV51793184; called by muse, mutect2, varscan2
- ARHGAP36 | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1460939004, COSV52263824; called by muse, mutect2, varscan2
- ARHGEF11 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); catalogued as COSV59357596; called by muse, mutect2, varscan2
- ARID1A | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.056); catalogued as COSV61386063; called by muse, mutect2, varscan2
- ARMC4 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV53463031; called by muse, mutect2, varscan2
- ARMC4 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as rs1279559573, COSV53467729; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV63438827; called by muse, mutect2, varscan2
- ARRB1 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 13/223 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1227831031, COSV63577156; called by muse, mutect2
- ASAH2 | c.337G>A p.G113R | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771104552, COSV61484273; called by muse, mutect2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | catalogued as COSV60417431; called by mutect2, varscan2
- ASCC3 | c.2929T>G p.S977A | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV61232369; called by muse, mutect2
- ASH1L | c.7388C>T p.S2463F (on ENST00000368346 / NM_001366177.2; = p.S2458F on NM_018489.3) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV64212439; called by muse, mutect2, varscan2
- ASH1L | c.6232C>T p.R2078C (on ENST00000368346 / NM_001366177.2; = p.R2073C on NM_018489.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs772388982, COSV64204956; called by muse, mutect2, varscan2
- ASIC2 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290030167, COSV63324569; called by muse, mutect2
- ASTN1 | c.3404G>A p.R1135K | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV62503813; called by muse, mutect2, varscan2
- ASTN1 | c.2482+1G>A p.X828_splice | Splice Site (SNP) | VAF 9/56 reads (16%) | catalogued as COSV56080984; called by muse, mutect2, varscan2
- ASTN1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs1314396634, COSV56081025; called by muse, mutect2, varscan2
- ATCAY | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1369613975, COSV56658380; called by muse, mutect2
- ATG2A | c.4981C>T p.P1661S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65968442; called by muse, mutect2, varscan2
- ATP11A | c.1253C>T p.T418I | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52120791; called by muse, mutect2, varscan2
- ATP12A | c.293C>T p.P98L | Missense Mutation (SNP) | VAF 31/304 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV54521459; called by muse, mutect2, varscan2
- ATP13A1 | c.625T>C p.F209L | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52290309; called by muse, mutect2, varscan2
- ATP13A5 | c.2079G>A p.M693I | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV60873706; called by muse, mutect2, varscan2
- ATP1A3 | c.483G>A p.M161I (on ENST00000545399 / NM_001256214.2; = p.M148I on NM_152296.5) | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.888); catalogued as COSV57487828; called by muse, mutect2, varscan2
- ATP1A4 | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63628077; called by muse, mutect2, varscan2
- ATP2A1 | c.2785G>A p.V929M | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV62870664; called by muse, mutect2, varscan2
- ATP6V0A4 | c.292-1G>A p.X98_splice | Splice Site (SNP) | VAF 12/72 reads (17%) | catalogued as rs776867749, CS002441, COSV59479329; called by muse, mutect2
- ATP8A1 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs773871555, COSV52545472; called by mutect2, varscan2
- ATP8B1 | c.2519G>A p.R840K | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1039404145, COSV52179137; called by muse, mutect2, varscan2
- ATP8B2 | c.3338C>T p.P1113L (on ENST00000672630; = p.P1080L on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs370515010; called by mutect2, varscan2
- ATP8B4 | c.2927C>T p.A976V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV52722276; called by muse, varscan2
- ATRNL1 | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV58108880; called by muse, mutect2, varscan2
- ATRNL1 | c.3635C>T p.S1212F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1554971646, COSV58108888; called by muse, mutect2, varscan2
- ATRNL1 | c.4102C>T p.R1368* | Nonsense Mutation (SNP) | VAF 16/97 reads (16%) | catalogued as rs1555125081, COSV58077266; called by muse, varscan2
- ATXN1 | c.1475T>A p.I492N | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55227929; called by muse, mutect2, varscan2
- B3GALT1 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 10/100 reads (10%) | catalogued as COSV59909606; called by muse, mutect2, varscan2
- BACH1 | c.1844A>G p.Q615R | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV54520606; called by muse, mutect2, varscan2
- BAZ1A | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1466489502, COSV100701154, COSV62408893; called by muse, mutect2, varscan2
- BCL6 | c.1430C>T p.S477F | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV51654939; called by muse, mutect2, varscan2
- BCO2 | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV63064580; called by muse, mutect2
- BEND3 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV64681993; called by muse, mutect2
- BEND7 | c.424C>G p.Q142E | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.288); catalogued as COSV61990702; called by muse, mutect2, varscan2
- BFSP2 | c.381A>T p.Q127H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV56591190; called by muse, mutect2, varscan2
- BIRC3 | c.176G>C p.G59A | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1470578400, COSV54819296; called by muse, mutect2, varscan2
- BIRC6 | c.8854G>A p.D2952N | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.041); catalogued as COSV70204241; called by muse, mutect2
- BMP15 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV53140815, COSV53141751; called by muse, mutect2
- BMP2 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | catalogued as COSV66579035; called by muse, mutect2, varscan2
- BMP2 | c.853A>G p.K285E | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV66579046; called by muse, mutect2, varscan2
- BMP4 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs752209771, COSV55416998; called by muse, mutect2, varscan2
- BMP5 | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV63704158; called by muse, mutect2
- BMP7 | c.1102A>C p.N368H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV67782181; called by muse, mutect2, varscan2
- BMPER | c.1951G>A p.E651K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.621); catalogued as COSV51821322; called by muse, mutect2
- BNIP5 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV71325798; called by muse, mutect2
- BPIFA2 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.148); catalogued as COSV53612375; called by muse, varscan2
- BPTF | c.1951C>T p.P651S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.122); catalogued as COSV58851786; called by muse, mutect2, varscan2
- BPTF | c.3444G>A p.M1148I | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58844683, COSV58846262; called by muse, mutect2, varscan2
- BRCA1 | c.3632C>T p.S1211F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as COSV58796978; called by muse, mutect2, varscan2
- BRCA2 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66456892; called by muse, mutect2
- BRDT | c.2389-1G>A p.X797_splice | Splice Site (SNP) | VAF 17/105 reads (16%) | catalogued as COSV62866884; called by muse, mutect2, varscan2
- BRINP2 | c.1254G>A p.W418* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV64179587; called by muse, mutect2, varscan2
- BRINP3 | c.1830G>A p.W610* | Nonsense Mutation (SNP) | VAF 47/248 reads (19%) | catalogued as COSV66537459; called by mutect2, varscan2
- BRSK1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV58665527; called by muse, mutect2, varscan2
- BTK | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.301); catalogued as COSV58122925; called by muse, mutect2, varscan2
- BTNL2 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66631759; called by muse, mutect2
- BUB1 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV57066307; called by muse, mutect2, varscan2
- BUB1 | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.757); catalogued as COSV57066317; called by muse, mutect2, varscan2
- BVES | c.958C>T p.H320Y | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58946553; called by muse, mutect2, varscan2
- C10orf120 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.058); catalogued as COSV61491897; called by muse, mutect2
- C15orf39 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 28/163 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.785); catalogued as COSV100641393; called by muse, mutect2, varscan2
- C15orf39 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as rs1030116295, COSV100641394; called by muse, mutect2, varscan2
- C19orf44 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs752485439, COSV55614180; called by muse, mutect2, varscan2
- C19orf57 | c.1984G>A p.D662N (on ENST00000586783 / NM_001345843.1; = p.D631N on NM_024323.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as rs752161253, COSV59248911; called by muse, mutect2, varscan2
- C1QC | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV65890003; called by muse, mutect2, varscan2
- C1R | c.1564G>A p.E522K (on ENST00000536053 / NM_001354346.2; = p.E508K on NM_001733.7) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.105); catalogued as COSV73383044; called by muse, mutect2, varscan2
- C1orf127 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65438589; called by muse, mutect2
- C1orf87 | c.750G>A p.V250= | Splice Region (SNP) | VAF 4/26 reads (15%) | catalogued as COSV64598348; called by mutect2, varscan2
- C6orf15 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs756329609, COSV52539684; called by muse, mutect2, varscan2
- C8B | c.1080G>A p.M360I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs267598670, COSV64779117; called by muse, mutect2, varscan2
- C9 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs764410729, COSV54678927, COSV54680338; called by muse, mutect2, varscan2
- C9orf135 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.494); catalogued as rs754494630, COSV65876282; called by muse, mutect2, varscan2
- CA7 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs372983215, COSV100623826; called by mutect2, varscan2
- CACHD1 | c.1226G>A p.G409D | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as rs367857134; called by muse, mutect2, varscan2
- CACNA1A | c.2398G>A p.E800K | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64193286; called by muse, mutect2
- CACNA1C | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59758698; called by mutect2, varscan2
- CACNA1D | c.6259G>A p.E2087K (on ENST00000350061 / NM_001128840.3; = p.E2107K on NM_000720.4) | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as rs762059527, COSV55436089, COSV55439012; called by muse, mutect2, varscan2
- CACNA1E | c.1800G>A p.M600I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs866685114, COSV62412899; called by muse, mutect2, varscan2
- CACNA1G | c.4327G>A p.G1443S | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61735679; called by muse, mutect2
- CACNA2D4 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.912); catalogued as rs954675574, COSV54957789; called by muse, mutect2, varscan2
- CACNA2D4 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99765929; called by muse, mutect2, varscan2
- CACNA2D4 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.337); catalogued as rs555700156, COSV54957400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMK1G | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs147371769; called by muse, mutect2, varscan2
- CAMKK2 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV61217103; called by muse, mutect2, varscan2
- CAMSAP3 | c.1088C>T p.S363F | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.054); catalogued as COSV50331755; called by muse, mutect2, varscan2
- CAND2 | c.2843C>T p.A948V (on ENST00000456430 / NM_001162499.2; = p.A855V on NM_012298.3) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV55993466; called by muse, mutect2
- CAP2 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368723417, COSV57735803; called by mutect2, varscan2
- CAPZA3 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868744411, COSV56849081, COSV56850605; called by muse, mutect2, varscan2
- CARD11 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.588); catalogued as rs1562490836, COSV67801341; called by muse, mutect2, varscan2
- CARD6 | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV54568047, COSV54568439; called by muse, mutect2, varscan2
- CARF | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.803); catalogued as COSV57547684; called by muse, mutect2, varscan2
- CARS2 | c.1051T>C p.S351P | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57288372; called by muse, mutect2
- CASP5 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs199936232; called by muse, mutect2, varscan2
- CASP8AP2 | c.3683C>T p.T1228I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52749210; called by muse, mutect2
- CASZ1 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs747359296, COSV59740091; called by muse, mutect2, varscan2
- CASZ1 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs150116767; called by muse, mutect2, varscan2
- CATSPER1 | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV56412893; called by muse, mutect2
- CATSPER4 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58794217; called by muse, mutect2, varscan2
- CATSPERB | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56432672; called by muse, mutect2, varscan2
- CAVIN4 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV56868029; called by muse, mutect2, varscan2
- CBLC | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs148127553, COSV54323396; called by muse, mutect2, varscan2
- CBLL1 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56028431; called by muse, varscan2
- CCDC105 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs1462378227, COSV52965283; called by muse, mutect2, varscan2
- CCDC141 | c.3025G>A p.D1009N | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.159); catalogued as COSV55378079, COSV55380367; called by muse, mutect2, varscan2
- CCDC170 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53341988; called by muse, mutect2, varscan2
- CCDC170 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0.015); catalogued as COSV53344866; called by muse, mutect2, varscan2
- CCDC178 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 8/45 reads (18%) | catalogued as COSV55792285; called by muse, mutect2, varscan2
- CCDC25 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1188357550, COSV62959324; called by muse, mutect2, varscan2
- CCDC63 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV57530324; called by muse, mutect2, varscan2
- CCDC82 | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758564028, COSV53595057; called by muse, mutect2, varscan2
- CCKAR | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV55161404, COSV55163388; called by muse, mutect2
- CCKBR | c.1147G>A p.A383T | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.656); catalogued as rs1451554986, COSV58104496; called by muse, mutect2
- CCM2L | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52951636; called by muse, mutect2
- CCNF | c.1492C>T p.H498Y | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.852); catalogued as COSV53542356; called by muse, mutect2, varscan2
- CCNJL | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99979609; called by muse, mutect2, varscan2
- CCR5 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52752700; called by muse, mutect2, varscan2
- CCR6 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV59475919; called by muse, mutect2, varscan2
- CCSER1 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61458502; called by muse, mutect2, varscan2
- CD101 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); catalogued as rs1362169599, COSV56716851; called by muse, varscan2
- CD163L1 | c.1514G>A p.W505* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV58022887; called by muse, mutect2, varscan2
- CD248 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV60937580; called by muse, mutect2, varscan2
- CD300E | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs147195509, COSV60789624; called by muse, mutect2, varscan2
- CD38 | c.375G>A p.W125* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV56890440; called by muse, mutect2, varscan2
- CD55 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs12135160, COSV58576732; called by muse, mutect2, varscan2
- CD7 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as COSV53940453; called by muse, mutect2, varscan2
- CD86 | c.249G>A p.M83I (on ENST00000330540 / NM_175862.5; = p.M77I on NM_006889.4) | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1030574173, COSV52609693; called by muse, mutect2, varscan2
- CD86 | c.976G>A p.D326N (on ENST00000330540 / NM_175862.5; = p.D320N on NM_006889.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as rs1282173979, COSV52605021; called by muse, mutect2, varscan2
- CD96 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV51920632; called by muse, mutect2, varscan2
- CDA | c.135G>T p.Q45H | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV66752218; called by muse, mutect2, varscan2
- CDADC1 | c.1108C>T p.P370S | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51912341; called by muse, mutect2, varscan2
- CDC14B | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55792808; called by muse, mutect2
- CDH10 | c.2303G>A p.W768* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | catalogued as rs1371278745, COSV52571997, COSV52593476; called by muse, mutect2
- CDH11 | c.493C>T p.H165Y | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51773546; called by muse, mutect2, varscan2
- CDH11 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51765159; called by muse, mutect2, varscan2
- CDH12 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 42/182 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs776746467, COSV66410447, COSV66438733; called by muse, mutect2, varscan2
- CDH17 | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.23); catalogued as COSV50337191; called by muse, mutect2, varscan2
- CDH17 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV50337259; called by muse, mutect2, varscan2
- CDH18 | c.1664G>A p.R555K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV56900038; called by muse, mutect2, varscan2
- CDH23 | c.6613C>T p.P2205S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs1411016237, COSV56483577; called by muse, mutect2, varscan2
- CDH26 | c.2393C>T p.S798F (on ENST00000348616 / NM_177980.4; = p.S131F on NM_021810.6) | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs766481135, COSV54847125; called by muse, mutect2, varscan2
- CDH6 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV54076383; called by muse, mutect2
- CDK12 | c.1756C>T p.P586S | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1462649581, COSV71002390; called by muse, mutect2
- CDK3 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV56914751; called by muse, mutect2, varscan2
- CDK5RAP1 | c.547T>G p.C183G | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59428488; called by muse, mutect2, varscan2
- CDKL5 | c.2623C>T p.R875W | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV66110150; called by muse, mutect2, varscan2
- CDR1 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.983); catalogued as COSV65164079, COSV65164644; called by muse, mutect2, varscan2
- CDX4 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1195667489, COSV65171852; called by muse, mutect2
- CEACAM1 | c.1028C>T p.S343F | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV50730905; called by muse, varscan2
- CEACAM18 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.92); PolyPhen benign (0.039); catalogued as COSV67283781; called by muse, mutect2
- CEACAM21 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.283); catalogued as rs782487033, COSV51816000; called by muse, mutect2, varscan2
- CEBPA | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57199325; called by muse, mutect2, varscan2
- CECR2 | c.4168C>T p.L1390F (on ENST00000342247 / NM_001290047.2; = p.L1206F on NM_001290046.1) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs376337845; called by mutect2, varscan2
- CELSR3 | c.4775C>T p.P1592L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV51132050; called by muse, mutect2, varscan2
- CEMIP2 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.659); catalogued as COSV65488883; called by muse, mutect2, varscan2
- CENPF | c.5304T>G p.D1768E | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV65278262; called by muse, mutect2, varscan2
- CENPF | c.8069G>A p.G2690E | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV65278268; called by muse, mutect2, varscan2
- CENPF | c.8402C>T p.S2801F | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65274442, COSV65278272; called by muse, mutect2, varscan2
- CEP126 | c.1990C>T p.H664Y | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.006); catalogued as COSV54829500; called by muse, mutect2
- CEP164 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54045353; called by muse, mutect2, varscan2
- CEP95 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); catalogued as COSV73609556; called by muse, mutect2, varscan2
- CES1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as rs756275539, COSV62089501; called by muse, mutect2
- CFAP221 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.314); catalogued as rs371359569; called by muse, mutect2, varscan2
- CFAP299 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as rs528144369, COSV63885198; called by muse, mutect2, varscan2
- CFAP46 | c.7135G>A p.E2379K | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.725); catalogued as COSV54157802; called by muse, mutect2
- CFAP46 | c.6028G>A p.D2010N | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV54157822; called by muse, mutect2, varscan2
- CFAP47 | c.4343C>A p.T1448N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV57976074; called by muse, mutect2, varscan2
- CFAP52 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55348339; called by muse, mutect2, varscan2
- CFAP54 | c.5215G>A p.D1739N | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100733160, COSV61574539; called by muse, mutect2, varscan2
- CFAP69 | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV60184848, COSV60185846; called by muse, mutect2, varscan2
- CFAP74 | c.4628G>A p.R1543Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.998); catalogued as rs367731790, COSV60587133; called by muse, mutect2, varscan2
- CFHR2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV66381992; called by muse, mutect2
- CFTR | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV50041592; called by muse, mutect2, varscan2
- CFTR | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV50085627, COSV99135247; called by muse, varscan2
- CGN | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV54972730; called by muse, mutect2
- CGNL1 | c.2716G>A p.G906R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777396993, COSV55573660; called by muse, mutect2, varscan2
- CHI3L2 | c.712G>A p.G238R | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as rs960872976, COSV63874705; called by muse, mutect2, varscan2
- CHL1 | c.3254G>A p.G1085E (on ENST00000397491 / NM_001253387.1; = p.G1101E on NM_006614.4) | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56603186; called by muse, mutect2, varscan2
- CHRD | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.854); catalogued as COSV52611527; called by muse, mutect2, varscan2
- CHRNA9 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758485973, COSV59575615; called by muse, mutect2, varscan2
- CHRNB1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60141923; called by muse, mutect2, varscan2
- CIC | c.1502C>T p.S501F | Missense Mutation (SNP) | VAF 23/138 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.502); catalogued as COSV50648919, COSV50669216; called by muse, mutect2, varscan2
- CILK1 | c.1820C>T p.T607I (on ENST00000350082 / NM_001375397.1; = p.T600I on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV63155651; called by muse, mutect2, varscan2
- CILP | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56027120; called by muse, mutect2, varscan2
- CIPC | c.1137A>T p.L379F | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62376993; called by muse, mutect2, varscan2
- CLCN3 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV61628213; called by muse, mutect2, varscan2
- CLCN6 | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as COSV56742520; called by muse, mutect2, varscan2
- CLIC6 | c.1564G>A p.A522T (on ENST00000360731 / NM_001317009.2; = p.A504T on NM_053277.3) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62449124; called by muse, mutect2
- CLIP4 | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60751829; called by muse, mutect2
- CLVS2 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1337157487, COSV51565601, COSV51566551; called by muse, mutect2
- CMYA5 | c.3107C>T p.S1036F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV71408858; called by muse, mutect2, varscan2
- CNGA2 | c.375G>A p.K125= | Splice Region (SNP) | VAF 18/127 reads (14%) | catalogued as COSV61705163; called by muse, mutect2, varscan2
- CNGA2 | c.1779G>A p.M593I | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV61704302; called by muse, mutect2, varscan2
- CNGB1 | c.2987G>A p.G996D | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99203674; called by muse, mutect2
- CNTN1 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61644330; called by muse, mutect2
- CNTN4 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61879131; called by muse, mutect2, varscan2
- CNTN5 | c.2972C>T p.S991F | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV54333704, COSV54346402; called by muse, mutect2, varscan2
- CNTNAP2 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV62144663, COSV62167074; called by muse, mutect2, varscan2
- CNTNAP2 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.18); catalogued as COSV62240163; called by muse, mutect2, varscan2
- CNTNAP4 | c.2387C>T p.S796F | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.991); catalogued as rs867085564, COSV56696352; called by muse, mutect2, varscan2
- CNTNAP5 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs765130255, COSV70494484; called by muse, mutect2, varscan2
- COL10A1 | c.694G>A p.G232S | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54574266; called by muse, mutect2, varscan2
- COL11A1 | c.4090C>T p.P1364S | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as COSV62193617; called by muse, mutect2
- COL11A1 | c.2887C>T p.P963S | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV62193640; called by muse, mutect2, varscan2
- COL11A2 | c.4558C>T p.R1520C (on ENST00000341947 / NM_080680.3; = p.R1413C on NM_080679.2) | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as rs934714603, COSV59494192; called by muse, mutect2, varscan2
- COL11A2 | c.2098G>A p.G700R (on ENST00000341947 / NM_080680.3; = p.G593R on NM_080679.2) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59501364; called by muse, mutect2, varscan2
- COL11A2 | c.1285-1G>A p.X429_splice (on ENST00000341947 / NM_080680.3; = p.X322_splice on NM_080679.2) | Splice Site (SNP) | VAF 17/81 reads (21%) | catalogued as COSV59501374; called by muse, mutect2, varscan2
- COL1A2 | c.2647G>A p.G883S | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51964140; called by muse, mutect2, varscan2
- COL1A2 | c.3337G>A p.D1113N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.425); catalogued as rs760490617, COSV51964152; called by mutect2, varscan2
- COL21A1 | c.2677G>A p.G893S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55175969; called by muse, mutect2, varscan2
- COL21A1 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.025); catalogued as rs375415415, COSV55176004; called by mutect2, varscan2
- COL22A1 | c.3620G>A p.G1207E | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768207247, COSV57333070; called by muse, mutect2, varscan2
- COL24A1 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV65312186; called by muse, mutect2, varscan2
- COL2A1 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as rs1437402366, COSV61533247; called by muse, mutect2
- COL2A1 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs976006680, COSV61531998; called by muse, mutect2, varscan2
- COL3A1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV58594914; called by muse, mutect2, varscan2
- COL3A1 | c.3898G>A p.E1300K | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100483265; called by muse, mutect2, varscan2
- COL4A1 | c.1883C>T p.S628F | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as rs1468687240, COSV65425834; called by muse, mutect2
- COL4A3 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67418987, COSV67421880; called by muse, mutect2, varscan2
- COL4A4 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM151513, COSV61629695; called by mutect2, varscan2
- COL4A4 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307140; called by muse, mutect2, varscan2
- COL4A4 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61629542; called by muse, mutect2, varscan2
- COL4A5 | c.1805G>A p.R602K | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as COSV60366552, COSV60369110; called by muse, mutect2, varscan2
- COL4A5 | c.4436G>A p.G1479E | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as CD951666, COSV60369149; called by muse, mutect2, varscan2
- COL4A6 | c.3892G>A p.G1298R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57874817; called by muse, mutect2, varscan2
- COL4A6 | c.1859G>A p.G620E | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777747305, COSV57874835; called by muse, mutect2, varscan2
- COL5A1 | c.2466G>A p.M822I | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.415); catalogued as COSV65673478; called by muse, mutect2
- COL5A1 | c.4154C>T p.P1385L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1418421771, COSV65672564; called by muse, mutect2, varscan2
- COL5A2 | c.3284G>A p.G1095E | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66411794, COSV66413749; called by muse, mutect2, varscan2
- COL6A3 | c.3019C>T p.P1007S | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.168); catalogued as COSV55087576; called by muse, mutect2, varscan2
- COL6A5 | c.5909A>T p.N1970I (on ENST00000312481; = p.N1966I on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55213121; called by muse, mutect2, varscan2
- COL9A1 | c.2182C>T p.P728S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.248); catalogued as rs1169371758, COSV57891254; called by muse, mutect2, varscan2
- COL9A1 | c.1052C>T p.S351L | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.462); catalogued as rs201035486, COSV100296071; called by mutect2, varscan2
- COL9A3 | c.739G>A p.G247S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59655275; called by muse, mutect2, varscan2
- CPB1 | c.755G>A p.R252K | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51576076, COSV51576763; called by muse, mutect2, varscan2
- CPED1 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs1223619941, COSV59998146; called by muse, mutect2, varscan2
- CPM | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58031793; called by muse, mutect2, varscan2
- CPNE4 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV70198839; called by muse, mutect2, varscan2
- CPT1C | c.772-1G>A p.X258_splice | Splice Site (SNP) | VAF 11/52 reads (21%) | catalogued as COSV54921587; called by muse, mutect2, varscan2
- CPXCR1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs762225008, COSV52164192; called by muse, mutect2, varscan2
- CPXM1 | c.2161G>A p.D721N | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV66046496; called by muse, varscan2
- CRB1 | c.3455G>A p.G1152E | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66329543, COSV66330761; called by muse, mutect2, varscan2
- CREB3L3 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.105); catalogued as COSV50253633; called by muse, mutect2, varscan2
- CRYBG1 | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.02); catalogued as COSV64814026; called by muse, mutect2, varscan2
- CSAG1 | c.206A>C p.K69T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.986); catalogued as COSV63400914; called by muse, varscan2
- CSMD1 | c.8507G>A p.G2836E (on ENST00000520002; = p.G2835E on NM_033225.6) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV59368610; called by muse, mutect2, varscan2
- CSMD1 | c.7427G>A p.R2476Q (on ENST00000520002; = p.R2475Q on NM_033225.6) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs746088122, COSV59327160, COSV59373995; called by mutect2, varscan2
- CSMD1 | c.6076C>T p.H2026Y (on ENST00000520002; = p.H2025Y on NM_033225.6) | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as COSV59368693; called by muse, mutect2, varscan2
- CSMD2 | c.4255G>A p.G1419R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53903397; called by muse, mutect2
- CSMD2 | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53949912; called by muse, varscan2
- CSMD2 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53949979; called by muse, mutect2, varscan2
- CSMD3 | c.3764C>T p.P1255L (on ENST00000297405 / NM_001363185.1; = p.P1151L on NM_052900.3) | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52285875; called by muse, mutect2, varscan2
- CSMD3 | c.1933G>A p.E645K (on ENST00000297405 / NM_001363185.1; = p.E541K on NM_052900.3) | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs780733307, COSV52256469, COSV99852540; called by muse, mutect2, varscan2
- CSNK1A1L | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV65790058; called by muse, mutect2
- CSRNP3 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs79015458, COSV58784290; called by muse, mutect2, varscan2
- CTNND2 | c.2788+1G>A p.X930_splice | Splice Site (SNP) | VAF 12/121 reads (10%) | catalogued as COSV58917692; called by muse, mutect2
- CTSV | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 20/91 reads (22%) | catalogued as rs1023394620, COSV52345559; called by muse, mutect2, varscan2
- CTTNBP2NL | c.96A>T p.L32F | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54746412; called by muse, mutect2, varscan2
- CXCR1 | c.484G>C p.G162R | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.56); catalogued as COSV55282734; called by muse, varscan2
- CYFIP2 | c.3097C>T p.L1033F (on ENST00000616178 / NM_001291722.2; = p.L1008F on NM_014376.4) | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV59048316; called by muse, mutect2, varscan2
- CYFIP2 | c.3377G>A p.S1126N (on ENST00000616178 / NM_001291722.2; = p.S1101N on NM_014376.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.162); catalogued as COSV59048366; called by muse, varscan2
- CYLC2 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV66339080; called by muse, mutect2
- CYP2C9 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV53251753; called by muse, mutect2, varscan2
- CYP2C9 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.355); catalogued as rs781370526, COSV53251762; called by muse, mutect2, varscan2
- CYP39A1 | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51497603; called by muse, mutect2
- CYP3A4 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV60503775; called by muse, mutect2, varscan2
- CYP3A5 | c.318+1G>A p.X106_splice | Splice Site (SNP) | VAF 28/132 reads (21%) | catalogued as rs747171434, COSV56122449; called by muse, varscan2
- CYP4A22 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as COSV53741911, COSV53742891; called by muse, mutect2, varscan2
- CYP4A22 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 76/463 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598633, COSV53741921; called by muse, mutect2, varscan2
- CYP4F3 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as rs138587161; called by muse, mutect2, varscan2
- CYP4F3 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 29/172 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141482165; called by muse, mutect2, varscan2
- CYP4Z1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1206792114, COSV61964908; called by muse, mutect2, varscan2
- CYSLTR1 | c.992G>A p.G331E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV64821072; called by muse, mutect2, varscan2
- D2HGDH | c.852C>T p.L284= | Splice Region (SNP) | VAF 15/79 reads (19%) | catalogued as rs757098685, COSV58322965; called by muse, mutect2, varscan2
- DAB1 | c.1583C>T p.S528L (on ENST00000371231; = p.S495L on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.94); catalogued as rs144227484, COSV64696646; called by muse, mutect2, varscan2
- DAB1 | c.1430C>T p.S477F (on ENST00000371231; = p.S444F on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV64696412; called by muse, varscan2
- DAB1 | c.1354C>T p.Q452* (on ENST00000371231; = p.Q419* on NM_021080.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV64692682, COSV64696908; called by muse, varscan2
- DACT1 | c.1444T>G p.S482A | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV60022899; called by muse, mutect2, varscan2
- DAZ2 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.874); catalogued as COSV66554603; called by mutect2, varscan2
- DCC | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.061); catalogued as rs774540293, COSV59086280, COSV59109601; called by muse, mutect2, varscan2
- DCC | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as COSV59127401; called by muse, mutect2, varscan2
- DCC | c.3788G>A p.G1263E | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as COSV101473287; called by muse, mutect2, varscan2
- DCC | c.4031G>A p.S1344N | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71439452; called by muse, mutect2, varscan2
- DCDC1 | c.2656C>T p.P886S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV60304716; called by muse, mutect2
- DCDC1 | c.2390G>A p.W797* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV60855245; called by muse, mutect2, varscan2
- DCLK3 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV69364368; called by muse, mutect2, varscan2
- DDI1 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.532); catalogued as COSV56390484; called by muse, mutect2
- DDIT4L | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV56767938; called by muse, mutect2, varscan2
- DDX31 | c.2552T>C p.V851A | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV55036917; called by muse, mutect2, varscan2
- DDX46 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV62800712; called by muse, mutect2
- DDX59 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.218); catalogued as COSV100494602; called by muse, mutect2, varscan2
- DDX60L | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV52710046; called by muse, mutect2, varscan2
- DEFB119 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/121 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as rs267605872, COSV59266560; called by muse, mutect2, varscan2
- DEFB125 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1205215462, COSV66703536; called by muse, mutect2, varscan2
- DEFB125 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1400652577, COSV66703540; called by muse, mutect2, varscan2
- DENND11 | c.385C>T p.P129S | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs1443688213, COSV72097786; called by muse, mutect2, varscan2
- DENND1A | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1243663517, COSV65354952; called by muse, mutect2, varscan2
- DENND1B | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52463329; called by muse, varscan2
- DENND2C | c.1757G>A p.R586Q (on ENST00000393274 / NM_001256404.2; = p.R529Q on NM_198459.4) | Missense Mutation (SNP) | VAF 84/356 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs753435776, COSV67923592; called by muse, mutect2, varscan2
- DENND5A | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60237093; called by muse, mutect2, varscan2
- DGKB | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as rs533895069, COSV51791441; called by muse, mutect2, varscan2
- DHRS2 | c.682G>A p.G228R | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV51633645; called by muse, varscan2
- DHTKD1 | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.074); catalogued as COSV53806132; called by muse, mutect2, varscan2
- DHX58 | c.1566C>T p.I522= | Splice Region (SNP) | VAF 16/67 reads (24%) | catalogued as rs782406125, COSV52427782; called by muse, mutect2, varscan2
- DICER1 | c.2483C>T p.S828F | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58620122; called by muse, mutect2, varscan2
- DIDO1 | c.5869C>T p.P1957S | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs867504145, COSV56631869; called by muse, mutect2, varscan2
- DLAT | c.1244T>C p.V415A | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV54772798; called by muse, mutect2, varscan2
- DLD | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs1020483871, COSV52739336; called by muse, mutect2, varscan2
- DLG1 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100015531; called by muse, mutect2
- DLG2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV54676338; called by muse, mutect2, varscan2
- DLGAP2 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1452739637, COSV70102970; called by muse, mutect2, varscan2
- DMBX1 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as rs867418264, COSV63602473; called by muse, mutect2, varscan2
- DMRTC2 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 17/194 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV54188025; called by muse, mutect2
- DMXL2 | c.3953C>T p.S1318F | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51853880; called by muse, mutect2
- DMXL2 | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV51853897; called by muse, mutect2
- DMXL2 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV51853914; called by muse, mutect2, varscan2
- DNAAF1 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.006); catalogued as rs1188239671, COSV57578553; called by muse, mutect2, varscan2
- DNAH1 | c.6139G>A p.E2047K | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV101326306; called by muse, mutect2, varscan2
- DNAH11 | c.9394C>T p.H3132Y | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV60974937; called by muse, varscan2
- DNAH11 | c.13084G>A p.D4362N | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs765948270, COSV60963315, COSV60974972; called by muse, mutect2, varscan2
- DNAH17 | c.4411G>A p.E1471K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.175); catalogued as COSV67759797; called by muse, mutect2, varscan2
- DNAH2 | c.12969T>G p.Y4323* | Nonsense Mutation (SNP) | VAF 44/204 reads (22%) | catalogued as COSV101209470; called by mutect2, varscan2
- DNAH2 | c.12970C>T p.P4324S | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.223); catalogued as rs144664374; called by mutect2, varscan2
- DNAH3 | c.7301G>A p.G2434D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54544360; called by muse, mutect2, varscan2
- DNAH3 | c.6034G>A p.D2012N | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54540649, COSV54554684; called by muse, mutect2
- DNAH5 | c.12628T>C p.Y4210H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54246073; called by muse, mutect2, varscan2
- DNAH5 | c.9991C>T p.Q3331* | Nonsense Mutation (SNP) | VAF 8/133 reads (6%) | catalogued as COSV54246082; called by muse, mutect2
- DNAH5 | c.9530C>T p.S3177L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54246092; called by muse, mutect2, varscan2
- DNAH5 | c.4588G>A p.E1530K | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV54230014; called by muse, mutect2, varscan2
- DNAH5 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54217167; called by muse, mutect2, varscan2
- DNAH5 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs779957324, COSV54206424; called by muse, mutect2, varscan2
- DNAH7 | c.5539G>A p.G1847S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as rs780786967, COSV56780296; called by mutect2, varscan2
- DNAH7 | c.4672G>A p.G1558R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56780320; called by muse, mutect2
- DNAH7 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as rs1206995675, COSV56759648; called by muse, mutect2, varscan2
- DNAH8 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV59472776; called by muse, varscan2
- DNAH8 | c.5119G>A p.D1707N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs267601015, COSV100543697, COSV59422745; called by mutect2, varscan2
- DNAH8 | c.10178C>T p.S3393F | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59472862; called by muse, mutect2, varscan2
- DNAH9 | c.2722G>A p.E908K | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV52370549; called by muse, mutect2, varscan2
- DNAH9 | c.4378C>T p.P1460S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.199); catalogued as rs774641556, COSV52332047; called by mutect2, varscan2
- DNAH9 | c.4379C>T p.P1460L | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.481); catalogued as COSV99306539; called by muse, mutect2
- DNAH9 | c.9215G>A p.G3072E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52370575; called by muse, mutect2
- DNAI1 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99646942; called by muse, mutect2
- DNAI1 | c.1550A>T p.E517V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99646943; called by muse, mutect2
- DNAI3 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV54005222; called by muse, mutect2, varscan2
- DNAJB12 | c.542C>T p.A181V (on ENST00000338820; = p.A147V on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV58761415; called by muse, mutect2
- DNM2 | c.1108T>C p.F370L | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV58969559; called by muse, mutect2
- DNMT1 | c.2930C>T p.S977F | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61582518; called by muse, mutect2
- DOCK1 | c.3557C>T p.T1186I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.756); catalogued as COSV54755279; called by muse, mutect2
- DOCK11 | c.2200C>T p.H734Y | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52245906; called by muse, varscan2
- DOCK7 | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52017987; called by muse, varscan2
- DOCK8 | c.4537C>T p.H1513Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV66623026; called by muse, mutect2, varscan2
- DPEP3 | c.1366A>G p.T456A | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV52052510; called by muse, mutect2, varscan2
- DPF1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.564); catalogued as COSV62793682; called by muse, mutect2
- DPP10 | c.1977G>A p.M659I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.374); catalogued as rs1024097964, COSV59714962; called by muse, mutect2
- DPYD | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60082595; called by mutect2, varscan2
- DRGX | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.01); catalogued as COSV65136513; called by muse, mutect2, varscan2
- DRP2 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs548126798, COSV65811501; called by muse, mutect2, varscan2
- DSC1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57142643; called by muse, mutect2, varscan2
- DSC2 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51866420; called by mutect2, varscan2
- DSCAM | c.4039C>T p.R1347C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs765825981, COSV68026060; called by muse, mutect2, varscan2
- DSCAM | c.2423G>A p.S808N | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.881); catalogued as COSV68033718; called by muse, mutect2, varscan2
- DSG1 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57138607; called by muse, mutect2, varscan2
- DSG1 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.296); catalogued as COSV57133919; called by muse, mutect2, varscan2
- DSP | c.5989G>A p.G1997R | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65794881; called by muse, mutect2, varscan2
- DSP | c.6635G>A p.G2212E | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV65792198; called by muse, mutect2
- DTNA | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.844); catalogued as COSV52020712; called by muse, mutect2
- DTX1 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55659007; called by muse, mutect2
- DVL3 | c.845T>G p.M282R | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV57457895; called by muse, mutect2, varscan2
- DYNAP | c.550G>A p.A184T (on ENST00000321600; = p.A158T on NM_173629.3) | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV58666018, COSV58666862; called by muse, mutect2
- DYNC2I1 | c.2204C>T p.S735F | Missense Mutation (SNP) | VAF 46/167 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.031); catalogued as rs773753472, COSV68106695; called by muse, mutect2, varscan2
- DYRK3 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV65607489; called by muse, mutect2
- DYSF | c.4658C>T p.P1553L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as rs1374069335, COSV50534553; called by muse, mutect2
- E2F4 | c.451+1G>A p.X151_splice | Splice Site (SNP) | VAF 8/75 reads (11%) | catalogued as COSV58876636; called by muse, mutect2, varscan2
- E2F7 | c.2647C>T p.P883S | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.327); catalogued as COSV59742755; called by muse, mutect2
- EBF2 | c.1286C>T p.S429F | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV68780058; called by muse, varscan2
- EBF3 | c.1552C>T p.P518S (on ENST00000355311 / NM_001375392.1; = p.P509S on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.616); catalogued as rs1238683008, COSV62480270; called by muse, mutect2
- EDA2R | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV53632645; called by muse, mutect2, varscan2
- EDIL3 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV56916147; called by mutect2, varscan2
- EFCAB3 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.054); catalogued as rs1346346128, COSV59504095; called by mutect2, varscan2
- EFCAB6 | c.4447G>A p.D1483N | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1242301493, COSV53070311; called by muse, mutect2, varscan2
- EFCAB7 | c.1294G>T p.E432* | Nonsense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as COSV64315221; called by muse, mutect2, varscan2
- EFL1 | c.3177C>T p.I1059= | Splice Region (SNP) | VAF 8/94 reads (9%) | catalogued as COSV51605914, COSV51609038; called by muse, mutect2
- EFL1 | c.2908C>T p.R970C | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757808847, COSV51609054; called by muse, mutect2, varscan2
- EFTUD2 | c.415C>T p.H139Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV68184460; called by muse, mutect2, varscan2
- EGFL6 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63634841; called by muse, mutect2, varscan2
- EGFLAM | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV59313901; called by muse, mutect2, varscan2
- EGFLAM | c.1898C>T p.S633F | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59296844; called by muse, mutect2
- EIF3B | c.1901C>T p.A634V | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.194); catalogued as COSV62804500; called by muse, mutect2, varscan2
- EIF4G1 | c.3124C>T p.R1042C (on ENST00000346169 / NM_198241.3; = p.R847C on NM_004953.5) | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs747077459, COSV59993171; called by muse, mutect2, varscan2
- ELFN2 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68744829; called by muse, mutect2, varscan2
- ELN | c.2072C>T p.P691L (on ENST00000320399 / NM_001278939.1; = p.P658L on NM_000501.4) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as CD991692, COSV52714270; called by muse, mutect2
- ELOA | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 22/327 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1042371389, COSV69311145; called by muse, mutect2
- ELOA2 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs769385321, COSV55294609; called by muse, mutect2, varscan2
- ELOA2 | c.1303G>A p.E435K | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV55300918, COSV55303840; called by muse, mutect2, varscan2
- ELOVL4 | c.395T>A p.F132Y | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV63954534; called by muse, mutect2
- EMSY | c.3781C>T p.P1261S | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV58264858; called by muse, mutect2
- EN1 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54632389; called by muse, mutect2, varscan2
- ENKUR | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs752499383, COSV100482047, COSV58632302; called by mutect2, varscan2
- ENPP4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 20/49 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); catalogued as COSV58089758; called by muse, mutect2, varscan2
- ENPP5 | c.940C>T p.Q314* | Nonsense Mutation (SNP) | VAF 9/165 reads (5%) | catalogued as COSV57908783; called by muse, mutect2
- ENPP5 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | catalogued as COSV57909701; called by muse, mutect2, varscan2
- ENTPD3 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs1213888544, COSV57195290; called by muse, mutect2, varscan2
- ENTR1 | c.402G>A p.K134= (on ENST00000357365 / NM_001039707.2; = p.K111= on NM_006643.4) | Splice Region (SNP) | VAF 19/73 reads (26%) | catalogued as rs756200366, COSV53742834; called by muse, mutect2, varscan2
- EP400 | c.8918T>C p.V2973A | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57783401; called by muse, mutect2, varscan2
- EPB41L2 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.01); catalogued as rs146731749; called by mutect2, varscan2
- EPB41L4A | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV54865906, COSV54878003; called by muse, mutect2, varscan2
- EPHA1 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); catalogued as COSV51975199; called by muse, mutect2
- EPHA2 | c.2199G>A p.M733I | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV64454419; called by muse, mutect2, varscan2
- EPHA3 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60716665; called by muse, mutect2
- EPHA6 | c.1905G>A p.M635I (on ENST00000389672 / NM_001080448.3; = p.M27I on NM_173655.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV67589956; called by muse, mutect2
- EPHA7 | c.2630G>A p.R877H | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs755970343, COSV65178391, COSV65183780, COSV65193538; called by mutect2, varscan2
- EPHA7 | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV65189517; called by muse, mutect2, varscan2
- EPHB6 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV63893196; called by muse, mutect2, varscan2
- ERAP1 | c.433T>A p.Y145N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57090811, COSV57092091; called by muse, mutect2, varscan2
- ERBB4 | c.2437G>A p.D813N | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61493352; called by muse, mutect2
- ERC2 | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs749708188, COSV55640138; called by muse, mutect2, varscan2
- ERCC2 | c.1659T>G p.Y553* | Nonsense Mutation (SNP) | VAF 18/110 reads (16%) | catalogued as COSV67264902; called by muse, mutect2, varscan2
- ERICH3 | c.3724G>A p.E1242K | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as COSV58613319; called by muse, mutect2, varscan2
- ERICH3 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs867745110, COSV58603843; called by muse, mutect2
- ERICH5 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs762941709, COSV59315425; called by mutect2, varscan2
- ERMAP | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1396399468, COSV60273344; called by muse, mutect2, varscan2
- ESPL1 | c.2474C>T p.T825I | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs1358715142, COSV57762231; called by muse, mutect2
- ETV7 | c.703C>T p.L235F | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV60318318; called by muse, mutect2
- EVI2B | c.576A>T p.K192N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as COSV100445547; called by muse, mutect2, varscan2
- EVI5 | c.2210C>T p.S737L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV64828203; called by muse, mutect2
- EXPH5 | c.2869G>A p.V957I | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.093); catalogued as COSV56207058; called by muse, mutect2
- EYA1 | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58159030; called by muse, mutect2, varscan2
- EYA1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.892); catalogued as rs561111097, CM136180, COSV58171414; called by muse, mutect2, varscan2
- EYA4 | c.1735A>T p.I579F (on ENST00000531901 / NM_001301013.1; = p.I573F on NM_004100.5) | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV62058119, COSV62058870; called by muse, mutect2, varscan2
- F11R | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57039970; called by muse, mutect2, varscan2
- F13A1 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV53559391; called by muse, mutect2, varscan2
- FADS2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1223411969, COSV53897278; called by muse, mutect2, varscan2
- FADS3 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | catalogued as COSV53880048; called by muse, mutect2, varscan2
- FAM135B | c.3506G>A p.G1169E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV52712378; called by muse, mutect2, varscan2
- FAM151A | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56365881; called by muse, mutect2, varscan2
- FAM162B | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV63920680; called by muse, mutect2, varscan2
- FAM186B | c.1137A>G p.I379M | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57723318; called by muse, mutect2, varscan2
- FAM20A | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56837998; called by muse, mutect2, varscan2
- FAM47A | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV60499194; called by muse, mutect2, varscan2
- FAM47A | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV60497510; called by muse, mutect2, varscan2
- FAM47A | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV60499203, COSV60500380; called by muse, mutect2, varscan2
- FAM47C | c.2173C>T p.H725Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.607); catalogued as COSV63729496; called by muse, mutect2, varscan2
- FAM53C | c.341C>T p.S114F | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV53512643; called by muse, mutect2, varscan2
- FAM71A | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV54236896; called by muse, mutect2, varscan2
- FAM83B | c.1379A>C p.N460T | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.761); catalogued as COSV60925820; called by muse, mutect2, varscan2
- FAM83B | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV60919550; called by muse, mutect2, varscan2
- FAM83B | c.2774G>A p.R925Q | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs181400966; called by muse, mutect2, varscan2
- FANCI | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV55525702; called by muse, mutect2, varscan2
- FAP | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV51859418; called by muse, mutect2, varscan2
- FAT3 | c.805G>T p.V269F | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV53160309; called by mutect2, varscan2
- FAT3 | c.12691C>T p.P4231S | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99967443; called by muse, mutect2, varscan2
- FAT4 | c.6445G>A p.D2149N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58673294; called by muse, mutect2, varscan2
- FBLN1 | c.1916G>A p.G639E | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59941541; called by muse, mutect2, varscan2
- FBLN7 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.974); catalogued as COSV55616343; called by muse, mutect2, varscan2
- FBN1 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs776942896, COSV57327494; called by mutect2, varscan2
- FBN3 | c.7189G>A p.D2397N | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV54469690; called by muse, mutect2, varscan2
- FBXO24 | c.989G>A p.G330E (on ENST00000241071 / NM_033506.3; = p.G368E on NM_012172.5) | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV53828799; called by muse, mutect2, varscan2
- FBXO40 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs376716888; called by muse, mutect2, varscan2
- FBXO40 | c.1700G>A p.G567E | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.656); catalogued as COSV57526796; called by muse, mutect2, varscan2
- FBXO9 | c.1150C>T p.H384Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV55054862, COSV99762652; called by muse, mutect2, varscan2
- FBXW12 | c.1038G>A p.W346* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV56485106; called by muse, mutect2, varscan2
- FCRL3 | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV63844252; called by muse, mutect2, varscan2
- FCRL5 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62518875; called by muse, varscan2
- FGA | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as COSV57393188; called by muse, mutect2, varscan2
- FGF21 | c.410C>G p.S137C | Missense Mutation (SNP) | VAF 40/240 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99711492; called by muse, mutect2
- FGL1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV67713453; called by muse, mutect2
- FGR | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64969384; called by muse, mutect2, varscan2
- FIG4 | c.2267G>A p.S756N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57790379; called by muse, mutect2, varscan2
- FILIP1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52738459; called by muse, mutect2, varscan2
- FILIP1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1256647931, COSV52738472; called by muse, mutect2, varscan2
- FIZ1 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.054); catalogued as COSV99684634; called by muse, mutect2
- FKBP1B | c.199-7C>T | Splice Region (SNP) | VAF 4/43 reads (9%) | catalogued as rs763976354, COSV99272877; called by mutect2, varscan2
- FLG | c.9533C>T p.S3178L | Missense Mutation (SNP) | VAF 43/401 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.526); catalogued as COSV64246844; called by muse, mutect2
- FLG | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 59/325 reads (18%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.978); catalogued as rs567082495, COSV64242945; called by muse, mutect2, varscan2
- FLI1 | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs760927892, COSV55643724, COSV55647564; called by muse, mutect2, varscan2
- FLNB | c.7526C>T p.S2509F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV55880201; called by muse, mutect2, varscan2
- FLRT2 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58141830; called by muse, mutect2
- FLRT2 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58148309; called by muse, mutect2, varscan2
- FLT4 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV56100460; called by muse, mutect2, varscan2
- FMNL2 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV56502313; called by muse, mutect2, varscan2
- FMO2 | c.1001C>T p.S334F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52949743; called by muse, mutect2
- FRAS1 | c.11120G>A p.W3707* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as COSV53638308; called by muse, mutect2, varscan2
- FREM1 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs763516184, COSV63087542; called by mutect2, varscan2
- FRMD5 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as rs765767175, COSV68724680; called by mutect2, varscan2
- FRMD7 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53748199; called by muse, varscan2
- FRMPD2 | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.388); catalogued as rs1395730158, COSV59722389; called by muse, mutect2
- FRMPD3 | c.3072G>A p.M1024I | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV52195910; called by muse, mutect2, varscan2
- FRS2 | c.943C>T p.P315S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54728778; called by muse, mutect2, varscan2
- FSHR | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 4/29 reads (14%) | catalogued as COSV58632100; called by muse, mutect2
- FSIP2 | c.18406G>A p.G6136R | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58096530; called by muse, mutect2
- FYB1 | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs775145174, COSV60954228; called by muse, mutect2, varscan2
- FYN | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV57619364; called by muse, mutect2, varscan2
- GABBR2 | c.1293T>G p.F431L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV52316141; called by muse, mutect2, varscan2
- GABPA | c.307+1G>A p.X103_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV61397324; called by muse, mutect2
- GABRA3 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV100942988; called by muse, mutect2, varscan2
- GABRB2 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.285); catalogued as COSV50935119; called by muse, mutect2, varscan2
- GABRE | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as rs757646574, COSV64818761, COSV64819994, COSV64821147; called by muse, varscan2
- GALNT13 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV67221429; called by muse, mutect2, varscan2
- GALNT14 | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV61109816; called by muse, mutect2, varscan2
- GALNT17 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as rs867271774, COSV61184399; called by muse, mutect2, varscan2
- GALNT5 | c.1483C>T p.L495F | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52040393; called by muse, mutect2
- GALNT9 | c.1727C>T p.A576V (on ENST00000328957 / NM_001122636.2; = p.A210V on NM_021808.3) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV61102316; called by muse, mutect2, varscan2
- GALNTL6 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV72491619; called by muse, mutect2, varscan2
- GAS2L3 | c.1226T>C p.L409S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV57158754; called by muse, mutect2, varscan2
- GATA1 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs781928506, COSV64962072, COSV64963204; called by muse, mutect2, varscan2
- GATA4 | c.1189C>T p.H397Y | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1554499095, COSV100632924; called by muse, mutect2, varscan2
- GCC1 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.454); catalogued as COSV50001867; called by muse, mutect2, varscan2
- GCG | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV64962069; called by muse, mutect2
- GCOM1 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.391); catalogued as COSV51094507; called by muse, mutect2
- GCSAML | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100825879, COSV63579149; called by muse, mutect2, varscan2
- GDAP1L1 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 40/378 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV61158609; called by muse, mutect2, varscan2
- GFRAL | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs749227939, COSV61229928; called by muse, mutect2, varscan2
- GFRAL | c.702G>A p.R234= | Splice Region (SNP) | VAF 17/78 reads (22%) | catalogued as COSV100475418; called by muse, mutect2, varscan2
- GHR | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as CM970648, COSV50124869; called by muse, mutect2, varscan2
- GIMAP6 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs865805939, COSV61032437; called by muse, mutect2
- GJA5 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.408); catalogued as COSV54782962; called by muse, mutect2
- GLCCI1 | c.1492T>G p.S498A | Missense Mutation (SNP) | VAF 21/321 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.143); catalogued as COSV99780511; called by muse, mutect2
- GLG1 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 12/100 reads (12%) | catalogued as COSV52664415; called by muse, mutect2, varscan2
- GLIS3 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as rs757118860, COSV67940990; called by muse, mutect2, varscan2
- GLRA3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368508904, COSV56870346; called by muse, mutect2, varscan2
- GLRB | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.962); catalogued as COSV52415619; called by muse, mutect2, varscan2
- GLRB | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.433); catalogued as COSV52412919; called by muse, mutect2, varscan2
- GMEB2 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as COSV56609073; called by muse, mutect2
- GMPR | c.868G>A p.G290S | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52474914; called by muse, mutect2, varscan2
- GNA11 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50026373; called by muse, mutect2, varscan2
- GNAT2 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.279); catalogued as rs983915440, COSV63554832, COSV63555145; called by muse, mutect2, varscan2
- GNPDA2 | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.478); catalogued as rs1404519255, COSV54948139; called by muse, mutect2, varscan2
- GOLGA3 | c.1706C>T p.S569L | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.124); catalogued as rs149188843; called by muse, mutect2, varscan2
- GP2 | c.995C>T p.A332V (on ENST00000381362 / NM_001007240.3; = p.A329V on NM_001502.4) | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as rs1241340871, COSV56894723, COSV56896042; called by muse, mutect2, varscan2
- GP2 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415494673, COSV56893778; called by mutect2, varscan2
- GP2 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV56896052; called by muse, mutect2, varscan2
- GP5 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59878336; called by muse, mutect2, varscan2
- GPAT3 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs752029936, COSV52359055; called by muse, mutect2
- GPC5 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV65617719, COSV65622282; called by muse, mutect2, varscan2
- GPC5 | c.1325G>A p.G442E | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs141144398, COSV65614552; called by muse, mutect2, varscan2
- GPR139 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs942765597, COSV58501549; called by muse, varscan2
- GPR149 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1302542683, COSV67669320; called by muse, mutect2
- GPR152 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV56887819; called by muse, mutect2, varscan2
- GPR171 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs775872022, COSV56392962; called by muse, mutect2, varscan2
- GPR176 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV54447699; called by muse, mutect2, varscan2
- GPR183 | c.960G>A p.M320I | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as rs778346385, COSV63120733; called by muse, mutect2, varscan2
- GPR45 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV51525739; called by muse, mutect2
- GPRC6A | c.1654C>T p.H552Y | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV59952573; called by muse, mutect2
- GPX5 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69079309; called by muse, mutect2
- GRAMD2A | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV59034913; called by muse, mutect2
- GRB14 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55741990; called by muse, mutect2
- GRB7 | c.1485G>A p.M495I | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.247); catalogued as COSV58450220; called by muse, mutect2, varscan2
- GRIA2 | c.884A>G p.Y295C | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV52402535; called by muse, mutect2, varscan2
- GRID1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV60043682; called by muse, mutect2
- GRID2 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1383722822, COSV56249117; called by muse, mutect2, varscan2
- GRIK3 | c.1393T>C p.Y465H | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV66145220; called by muse, varscan2
- GRIN2A | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.883); catalogued as COSV58052167; called by muse, varscan2
- GRIN2B | c.2978G>A p.S993N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV74207325; called by muse, mutect2, varscan2
- GRIN2B | c.2687C>T p.S896F | Missense Mutation (SNP) | VAF 37/180 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV74207327; called by muse, mutect2, varscan2
- GRM2 | c.1011G>A p.W337* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV56586832; called by muse, mutect2, varscan2
- GRM3 | c.53G>A p.G18E | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV64466563; called by muse, mutect2, varscan2
- GRM5 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59623174; called by muse, varscan2
- GRTP1 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV58151606; called by muse, mutect2, varscan2
- GSK3B | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51772817; called by muse, mutect2, varscan2
- GUCA2A | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100813034, COSV63691489; called by muse, mutect2, varscan2
- GUCY2C | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs192356391, COSV53788241; called by muse, mutect2, varscan2
- GUCY2F | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV54307091; called by muse, mutect2, varscan2
- GZMH | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53539249; called by muse, mutect2
- H1-2 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs751385999, COSV59192012; called by mutect2, varscan2
- HABP2 | c.1622C>T p.T541I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63493252; called by muse, mutect2
- HAP1 | c.567G>A p.W189* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as COSV57880262; called by muse, mutect2
- HAUS5 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52549410; called by muse, mutect2
- HCFC1 | c.4228C>T p.P1410S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV60076433; called by muse, mutect2, varscan2
- HCN2 | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV52118001; called by muse, mutect2, varscan2
- HCN4 | c.2536C>T p.P846S | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); catalogued as COSV56086526; called by muse, mutect2, varscan2
- HCRTR2 | c.85T>A p.L29I | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV63798427; called by muse, mutect2, varscan2
- HCRTR2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs766006062, COSV63793711, COSV99057010; called by mutect2, varscan2
- HDAC9 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs866808573, COSV67782770; called by muse, mutect2
- HDAC9 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67782810; called by muse, mutect2
- HDAC9 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67780769; called by muse, mutect2, varscan2
- HDC | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143418383; called by muse, mutect2, varscan2
- HDLBP | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.087); catalogued as COSV60499867; called by muse, mutect2
- HEATR5B | c.2318C>T p.P773L | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51848390, COSV51856322; called by muse, mutect2
- HECW1 | c.700C>T p.Q234* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV67830520; called by muse, mutect2, varscan2
- HELB | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as rs755166356, COSV56075319; called by mutect2, varscan2
- HEPACAM2 | c.383G>A p.G128E (on ENST00000394468 / NM_001039372.4; = p.G116E on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.716); catalogued as COSV59057822; called by muse, mutect2
2,505 further variants in this file (1,302 protein-altering or splice-affecting, 1,121 silent, 82 other) are not listed here.
